CCDI case PBBXEP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/ae8f7d13-d462-4bab-b30d-ddba810221e7

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Alveolar soft part sarcoma: ICD-O-3 morphology code: 9581/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 13.1 years (4,790 days).

Biospecimens (3 samples)
- Sample 0DJQZD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJR1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DJR20: Tissue type: Tumor; Specimen type: Solid Tissue.
